Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3667, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3667-01A (Primary Tumor).

Diagnosis/ diagnoses:

Resected section of (sigmoid) colon with a colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending to within 8 cm of a resection margin and encircling the intestinal wall over a length of 7 cm. Invasive tumor spread to the muscularis propria. Oral and aboral resection margins are tumor-free. Twenty-two mesocolic lymph nodes are tumor-free and have uncharacteristically reactive lesions.

Stage of tumor is therefore: pT2 pN0 (0/22) L0 V0; G2

Follow-up report:

As requested an examination was initiated in relation to the question over microsatellite instability of the colon tumor.

According to the current consultation report (see appendix) there is no further evidence of the presence of significant tumor disposition, particularly of the HNPCC/ Lynch syndrome type.

Source: NCI Genomic Data Commons file 34bf2fa0-9dc7-4664-9dca-48584d71614a (TCGA-AA-3667.5D3DA8C3-0854-439D-B2F3-2F9016A78B9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).